MMRF case MMRF_2093 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8eae1d53-0c69-4946-b987-d38cb932ee01

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.2 years (18,691 days); ISS stage: II; Days to last known disease status: 963 days (2.6 years); Days to last follow up: 963 days (2.6 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 43 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 57 days; Days to treatment end: 123 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 57 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 177 days; Days to treatment end: 177 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 179 days; Days to treatment end: 179 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 253 days; Days to treatment end: 531 days (1.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 827 days (2.3 years); Days to treatment end: 829 days (2.3 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 827 days (2.3 years); Days to treatment end: 843 days (2.3 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 827 days (2.3 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 855 days (2.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 963.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -11 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.752 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 499 mg/dL; Immunoglobulin G 4.85 g/L; Immunoglobulin A 26.4 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 1.73 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 287 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 34 g/L; Total Protein 8 g/dL; Glucose 6.55 mmol/L; C-Reactive Protein 0.54 mg/dL.
- Day 79 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.727 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 32 mg/dL; Immunoglobulin G 5.22 g/L; Immunoglobulin A 2.01 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 7.98 mmol/L.
- Day 183 (ECOG 1): Immunoglobulin G 6.17 g/L; Immunoglobulin A 2.24 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 5.15 mmol/L; Leukocytes 1.1 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 1.85 mmol/L; Albumin 27 g/L; Total Protein 5.7 g/dL; Glucose 7.76 mmol/L.
- Day 248: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.85 mg/dL; Hemoglobin 6.45 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 7.54 mmol/L.
- Day 353: Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Immunoglobulin G 8.19 g/L; Immunoglobulin A 0.249 g/L; Immunoglobulin M 0.532 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 7.48 mmol/L.
- Day 437 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 7.64 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.275 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 6.6 g/dL; Glucose 11.8 mmol/L.
- Day 534 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 4.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.02 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.444 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 8 g/dL; Glucose 6.55 mmol/L.
- Day 610 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 3.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.56 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.703 g/L; Immunoglobulin M 0.338 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 10.7 mmol/L.
- Day 660 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.92 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 0.987 g/L; Immunoglobulin M 0.362 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 38 g/L; Total Protein 7.5 g/dL; Glucose 12.4 mmol/L.
- Day 751: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 106 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 3.52 g/L; Immunoglobulin M 0.493 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 7.3 g/dL; Glucose 10.4 mmol/L.
- Day 879: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.489 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 7.5 g/dL; Glucose 10.8 mmol/L.
- Day 953: Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.043 mg/dL; Immunoglobulin G 6.51 g/L; Immunoglobulin A 0.567 g/L; Immunoglobulin M 0.137 g/L; Hemoglobin 5.15 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 8.53 mmol/L.

Other clinical attributes
- Day -11: Weight: 114 kg; Height: 172 cm.

Biospecimens (2 samples)
- Sample MMRF_2093_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -11 days.
- Sample MMRF_2093_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -11 days.
